Somatic mutation profile of tumor specimen ALCH-B4CX-TTP1-A (aliquot ALCH-B4CX-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4CX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,268 days).
Specimen ALCH-B4CX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 013cddb8-997d-4439-9393-6df6e60ea686.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4CX-NB1-A (Blood Derived Normal), aliquot ALCH-B4CX-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c7bb018-dea3-4d5a-b1aa-2ce0902bba76

The open-access MAF lists 58 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, RNA 4, Nonsense Mutation 3, Intron 2, 5'UTR 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 115/606 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 96/476 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL121845.3 | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 42/188 reads (22%) | catalogued as rs1046654126; called by muse, mutect2, varscan2
- ATP1A4 | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 89/503 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769982611; called by muse, mutect2, varscan2
- COL1A2 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 56/685 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779358259, COSV51954132; called by muse, mutect2
- COL6A3 | c.8725G>A p.A2909T | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.059); catalogued as rs201917052, COSV55091157; ClinVar: likely benign; called by muse, mutect2
- CTNND2 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1483677548; called by muse, mutect2, varscan2
- EYS | c.30C>A p.S10R | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.296); catalogued as COSV60981955; called by muse, mutect2
- FBN1 | c.1469A>T p.D490V | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CD040175, COSV57315360; called by muse, mutect2
- HMCN2 | c.12738G>T p.W4246C | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52984274; called by muse, mutect2, varscan2
- IGHV3-33 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs374974779; called by muse, mutect2
- OR5D14 | c.289T>A p.F97I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59455243; called by muse, mutect2, varscan2
- PATE3 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV71323302; called by muse, mutect2
- PCDH11X | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 15/278 reads (5%) | catalogued as COSV100014044; called by muse, mutect2
- REM1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52428766; called by muse, mutect2, varscan2
- TG | c.3406C>T p.R1136W | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs116642273; called by muse, mutect2
- TTLL6 | c.1655A>T p.E552V (on ENST00000393382 / NM_001130918.3; = p.E245V on NM_173623.3) | Missense Mutation (SNP) | VAF 94/424 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64979452; called by muse, mutect2, varscan2
- ZNF213 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as rs1410245377; called by muse, mutect2
- BDNF | c.588C>G p.C196W | Missense Mutation (SNP) | VAF 31/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C2CD3 | c.3610A>T p.I1204F | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CCSAP | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CELF5 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); called by muse, mutect2
- CFAP74 | c.2768C>T p.S923L | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2
- CTNNA2 | c.1981C>A p.Q661K | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.439); called by muse, mutect2
- DDX5 | c.829A>T p.M277L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- DSCAM | c.2248T>A p.S750T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GABRA2 | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2
- HERC6 | c.1184G>C p.R395T | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- IDH3B | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 36/224 reads (16%) | called by muse, mutect2, varscan2
- IPP | c.1373A>T p.Y458F | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- KTN1 | c.2473G>T p.A825S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PMS1 | c.2086A>G p.M696V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUBCNL | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- SMG8 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SNIP1 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TANC2 | c.412_413del p.T138Cfs*7 | Frame Shift Del (DEL) | VAF 31/231 reads (13%) | called by mutect2, varscan2
- TSC1 | c.1573A>T p.S525C | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ZYX | c.1296C>A p.Y432* | Nonsense Mutation (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- ADGRG5 | c.466C>T p.L156= | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- ART3 | c.153C>T p.Y51= | Silent (SNP) | VAF 35/224 reads (16%) | catalogued as rs746724267, COSV61914566; called by muse, mutect2, varscan2
- FSIP2 | c.3438A>G p.Q1146= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- GON4L | c.3012C>A p.L1004= | Silent (SNP) | VAF 13/156 reads (8%) | called by muse, mutect2
- IDH3B | c.774G>T p.V258= | Silent (SNP) | VAF 34/219 reads (16%) | called by muse, mutect2, varscan2
- MYO1C | c.1884C>G p.P628= (on ENST00000648651 / NM_001080779.2; = p.P593= on NM_033375.5) | Silent (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- OR2D3 | c.186C>T p.I62= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- PCF11 | c.3240A>C p.G1080= | Silent (SNP) | VAF 33/311 reads (11%) | called by muse, mutect2, varscan2
- SIGLECL1 | c.360C>A p.I120= | Silent (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2, varscan2
- TRPM5 | c.816C>T p.L272= | Silent (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- WFDC1 | c.75C>G p.L25= | Silent (SNP) | VAF 15/253 reads (6%) | called by muse, mutect2
- ZBTB7B | c.990G>A p.L330= (on ENST00000292176; = p.L364= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as rs747147627; called by muse, mutect2, varscan2
- ADAM21P1 | n.841C>T | RNA (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2, varscan2
- CDRT15P3 | n.473G>A | RNA (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- FRAS1 | c.5856+66T>C | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- GLB1L3 | c.-18C>T | 5'UTR (SNP) | VAF 21/91 reads (23%) | catalogued as rs1298046913; called by muse, mutect2, varscan2
- LUC7L3 | c.*33+34T>C | Intron (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159745 G>A | 5'Flank (SNP) | VAF 38/174 reads (22%) | catalogued as rs796298062; called by muse, mutect2, varscan2
- SNORD115-11 | n.9G>A | RNA (SNP) | VAF 20/308 reads (6%) | catalogued as rs770132253; called by muse, mutect2
- SSPOP | n.9153G>T | RNA (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
